Somatic mutation profile of tumor specimen 0DQQBV from CCDI case PBCFFU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 2.6 years (948 days).
Specimen 0DQQBV: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cbd7ce26-5f88-4cb0-ad32-c90dc9ba9a0c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQQCS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be74a536-4fcf-4c42-a512-3212a7e6482d

The open-access MAF lists 37 somatic variants for this specimen: 23 protein-altering or splice-affecting, 9 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 9, Intron 4, Nonsense Mutation 4, Frame Shift Del 3, In Frame Del 2, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR4 | c.1648G>C p.V550L | Missense Mutation (SNP) | VAF 721/1029 reads (70%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52800715, COSV52802492, COSV52804538; called by muse, mutect2, varscan2
- ALB | c.1794del p.K598Nfs*10 | Frame Shift Del (DEL) | VAF 74/247 reads (30%) | catalogued as rs75000326, CM940026; ClinVar: not provided; called by pindel, varscan2
- ECI2 | c.1183_1184del p.*395Mfs*7 (on ENST00000380118 / NM_206836.3; = p.*365Mfs*7 on NM_006117.2) | Frame Shift Del (DEL) | VAF 72/285 reads (25%) | catalogued as rs1561646279; called by pindel, varscan2
- PPRC1 | c.2819dup p.P941Tfs*75 | Frame Shift Ins (INS) | VAF 46/150 reads (31%) | catalogued as rs768056539; called by mutect2, varscan2
- RAPH1 | c.1261C>T p.R421* (on ENST00000319170 / NM_213589.3; = p.R473* on NM_203365.4) | Nonsense Mutation (SNP) | VAF 56/672 reads (8%) | catalogued as rs541215148, COSV57350825; called by muse, mutect2
- SLC34A3 | c.956C>G p.T319R | Missense Mutation (SNP) | VAF 88/111 reads (79%) | SIFT tolerated (0.09); PolyPhen benign (0.301); catalogued as rs769622295, COSV63187705; called by muse, mutect2, varscan2
- TGFBR1 | c.829T>C p.W277R | Missense Mutation (SNP) | VAF 313/382 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100895368; called by muse, mutect2, varscan2
- BMPR2 | c.1127A>T p.E376V | Missense Mutation (SNP) | VAF 13/382 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); called by muse, mutect2
- CARD10 | c.620A>G p.Y207C | Missense Mutation (SNP) | VAF 177/447 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CDKN2A | c.290_319del p.L97_V106del | In Frame Del (DEL) | VAF 213/313 reads (68%) | called by mutect2, pindel, varscan2
- ECEL1 | c.620A>C p.D207A | Missense Mutation (SNP) | VAF 54/532 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ELF1 | c.1804T>C p.F602L | Missense Mutation (SNP) | VAF 116/303 reads (38%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ERC1 | c.2616del p.K872Nfs*7 (on ENST00000360905 / NM_178040.4; = p.K844Nfs*7 on NM_178039.4) | Frame Shift Del (DEL) | VAF 60/354 reads (17%) | called by mutect2, pindel, varscan2
- FCGBP | c.6819C>G p.D2273E | Missense Mutation (SNP) | VAF 83/594 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- FGFR2 | c.78T>A p.S26R | Missense Mutation (SNP) | VAF 96/298 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- FGFR4 | c.2257G>T p.E753* | Nonsense Mutation (SNP) | VAF 287/441 reads (65%) | called by muse, mutect2, varscan2
- KCP | c.1135C>T p.Q379* (on ENST00000620378; = p.Q436* on NM_001366122.1) | Nonsense Mutation (SNP) | VAF 100/288 reads (35%) | called by muse, mutect2, varscan2
- MORC1 | c.105G>T p.L35F | Missense Mutation (SNP) | VAF 116/339 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MYO16 | c.937G>T p.E313* | Nonsense Mutation (SNP) | VAF 111/259 reads (43%) | called by muse, mutect2, varscan2
- PIMREG | c.313_321del p.Q105_G107del | In Frame Del (DEL) | VAF 54/248 reads (22%) | called by mutect2, pindel, varscan2
- SEC24D | c.3052G>T p.D1018Y | Missense Mutation (SNP) | VAF 126/350 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TEX13A | c.1187G>C p.C396S | Missense Mutation (SNP) | VAF 274/606 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDR64 | c.823C>A p.L275I | Missense Mutation (SNP) | VAF 60/210 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- ANXA8L1 | c.297C>T p.A99= | Silent (SNP) | VAF 99/393 reads (25%) | called by muse, mutect2, varscan2
- B3GNT8 | c.781C>A p.R261= | Silent (SNP) | VAF 97/338 reads (29%) | catalogued as rs763742733, COSV54200063; called by muse, mutect2, varscan2
- KCNN4 | c.1215C>G p.A405= | Silent (SNP) | VAF 165/654 reads (25%) | called by muse, mutect2, varscan2
- LDB3 | c.531C>T p.A177= | Silent (SNP) | VAF 24/575 reads (4%) | catalogued as rs776893998; called by muse, mutect2
- NUP188 | c.1173G>A p.S391= | Silent (SNP) | VAF 310/375 reads (83%) | catalogued as rs772997394; called by muse, varscan2
- OR2Z1 | c.438C>A p.G146= | Silent (SNP) | VAF 70/241 reads (29%) | called by muse, mutect2, varscan2
- PLPP6 | c.486G>A p.G162= | Silent (SNP) | VAF 222/271 reads (82%) | called by muse, mutect2, varscan2
- PTPRQ | c.5166G>C p.L1722= (on ENST00000616559; = p.L1680= on NM_001145026.2) | Silent (SNP) | VAF 143/645 reads (22%) | called by muse, mutect2, varscan2
- RARB | c.174G>A p.P58= | Silent (SNP) | VAF 137/373 reads (37%) | catalogued as rs770431263; called by muse, mutect2, varscan2
- ARL13A | c.*390G>T | 3'UTR (SNP) | VAF 30/63 reads (48%) | called by muse, mutect2, varscan2
- ARMCX4 | c.1038+2997C>A | Intron (SNP) | VAF 115/291 reads (40%) | called by muse, mutect2, varscan2
- MYT1L | c.2027-39C>T | Intron (SNP) | VAF 43/176 reads (24%) | catalogued as COSV67732884; called by muse, mutect2, varscan2
- NOX4 | c.58-158G>A | Intron (SNP) | VAF 77/287 reads (27%) | called by muse, mutect2, varscan2
- TOGARAM2 | c.2722+38C>A | Intron (SNP) | VAF 38/139 reads (27%) | called by muse, mutect2, varscan2
